Somatic mutation profile of tumor specimen TCGA-38-4631-01A (aliquot TCGA-38-4631-01A-01D-1753-08) from TCGA case TCGA-38-4631, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.7 years (26,538 days).
Specimen TCGA-38-4631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14826ad4-fe64-4f31-bb3e-8e2d57ad7f5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-38-4631-11A (Solid Tissue Normal), aliquot TCGA-38-4631-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/374e13e1-98a8-4b65-94da-0d78ae51df5a

The open-access MAF lists 798 somatic variants for this specimen: 603 protein-altering or splice-affecting, 169 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 494, Silent 169, Nonsense Mutation 55, Splice Site 22, Frame Shift Del 19, Intron 13, RNA 7, Splice Region 6, Frame Shift Ins 5, 5'UTR 2, 3'Flank 2, Translation Start Site 2.

Variants (750 of 798; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 77/115 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM150818, COSV56765799, COSV56766683; called by muse, mutect2, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEGF10 | c.1976-1G>A p.X659_splice | Splice Site (SNP) | VAF 14/33 reads (42%) | catalogued as rs1057519152, COSV57255483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54052220; called by muse, mutect2, varscan2
- AAK1 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV68646360; called by muse, mutect2, varscan2
- AASS | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV62791502; called by muse, mutect2, varscan2
- ABCA13 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70040416; called by muse, mutect2, varscan2
- ABCA13 | c.5636G>T p.R1879L | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV70026133, COSV70042106; called by muse, mutect2, varscan2
- ABCA6 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV52644015; called by muse, mutect2, varscan2
- ABCC12 | c.2900G>C p.R967P | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.665); catalogued as rs372962244, COSV60917621; called by muse, mutect2, varscan2
- ACACB | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV58130354, COSV58143525, COSV58144420; called by muse, mutect2, varscan2
- ACIN1 | c.3524G>T p.R1175L | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV52974684, COSV52981343; called by muse, mutect2, varscan2
- ACIN1 | c.3103A>T p.T1035S | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV52981368; called by muse, varscan2
- ACP3 | c.1043G>T p.S348I | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV60488317; called by muse, mutect2
- ACTL9 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs142929347, COSV61007030; called by muse, mutect2, varscan2
- ADAM2 | c.1847G>T p.C616F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55867394; called by muse, mutect2, varscan2
- ADAM29 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 29/173 reads (17%) | catalogued as COSV100822034; called by muse, mutect2, varscan2
- ADAMTS19 | c.807G>T p.M269I | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV50789940; called by muse, mutect2, varscan2
- ADCK1 | c.1300A>G p.T434A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1324049113, COSV99451795; called by muse, mutect2, varscan2
- ADGRB3 | c.3575T>C p.V1192A | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs200962523, COSV53257846; called by muse, mutect2, varscan2
- ADGRG4 | c.7222G>C p.E2408Q | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV54965180; called by muse, mutect2, varscan2
- ADRA1D | c.1677C>G p.Y559* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV65241841; called by muse, mutect2, varscan2
- AGBL1 | c.960del p.V322Wfs*10 | Frame Shift Del (DEL) | VAF 30/159 reads (19%) | catalogued as COSV101222814; called by mutect2, pindel, varscan2
- AGBL1 | c.1354T>A p.S452T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV101223269; called by muse, mutect2, varscan2
- AGBL1 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV101223272; called by muse, mutect2, varscan2
- AIFM1 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.622); catalogued as COSV54857380; called by muse, mutect2, varscan2
- AIG1 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV51632764; called by muse, mutect2, varscan2
- ALDH8A1 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55644000; called by muse, mutect2, varscan2
- ALMS1 | c.5071G>T p.V1691F | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs758247002, COSV52520236; called by muse, mutect2, varscan2
- ALS2CL | c.1232G>C p.C411S | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV59673356; called by muse, mutect2, varscan2
- ANKK1 | c.883C>A p.R295S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV58273997; called by muse, mutect2, varscan2
- ANKRD44 | c.1539-1G>A p.X513_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV56562075, COSV99985113; called by muse, mutect2, varscan2
- ANKRD44 | c.1539-2A>C p.X513_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99985120; called by muse, mutect2, varscan2
- ANKZF1 | c.929A>C p.K310T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV55478532; called by muse, mutect2, varscan2
- APC | c.6937G>T p.A2313S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1028675068, COSV57334609, COSV57376245; called by muse, mutect2, varscan2
- APOB | c.4414G>T p.D1472Y | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51949784; called by muse, mutect2, varscan2
- APOL6 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.154); catalogued as COSV68749736; called by muse, mutect2, varscan2
- ARFGEF3 | c.2051T>A p.L684H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52469006; called by muse, mutect2, varscan2
- ARHGAP17 | c.461G>T p.R154M | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51511482; called by muse, mutect2, varscan2
- ARHGAP24 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67834103; called by muse, mutect2
- ARHGEF5 | c.4122G>C p.K1374N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV50217524; called by muse, mutect2, varscan2
- ARID1A | c.4070A>T p.Q1357L | Missense Mutation (SNP) | VAF 75/245 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV61387446; called by muse, varscan2
- ARID1B | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.525); catalogued as COSV51677672; called by muse, mutect2
- ARID2 | c.1331-1G>T p.X444_splice | Splice Site (SNP) | VAF 14/63 reads (22%) | catalogued as COSV57598791, COSV57613129; called by muse, mutect2, varscan2
- ARMCX2 | c.66C>A p.Y22* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV57531018; called by muse, mutect2, varscan2
- ARNTL | c.221+1G>T p.X74_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | catalogued as COSV62988544; called by muse, mutect2, varscan2
- ASAP1 | c.1653G>T p.R551S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100727334; called by muse, mutect2
- ASTN2 | c.2728T>C p.Y910H (on ENST00000313400 / NM_001365069.1; = p.Y859H on NM_014010.5) | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57812728; called by muse, mutect2, varscan2
- ASTN2 | c.1943C>G p.S648C (on ENST00000313400 / NM_001365069.1; = p.S597C on NM_014010.5) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57812740, COSV57817008; called by muse, mutect2, varscan2
- ATP10D | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs1560441760, COSV56712406; called by muse, mutect2
- ATP10D | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV56712416; called by muse, mutect2, varscan2
- ATP11C | c.2232G>T p.W744C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV59572490; called by muse, mutect2, varscan2
- ATP1B1 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs764962595, COSV63180009; called by muse, mutect2, varscan2
- ATP6AP2 | c.959T>G p.V320G (on ENST00000378438; = p.V321G on NM_005765.3) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65798252; called by muse, mutect2, varscan2
- ATPSCKMT | c.560G>C p.R187P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725879; called by muse, mutect2, varscan2
- ATRX | c.4810-1G>T p.X1604_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100970856, COSV64872875, COSV64883435; called by muse, mutect2, varscan2
- ATRX | c.242G>T p.R81M | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64870040; called by muse, mutect2, varscan2
- BAZ2B | c.5455G>T p.G1819C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58608767, COSV58612227; called by muse, mutect2, varscan2
- BCORL1 | c.2134A>T p.T712S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV54405427; called by muse, mutect2, varscan2
- BMX | c.1170C>A p.H390Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV59593213; called by muse, mutect2, varscan2
- BPIFB6 | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV62756477; called by muse, mutect2, varscan2
- BRAT1 | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100385159, COSV58093986; called by muse, mutect2, varscan2
- BRCA2 | c.8152A>G p.I2718V | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV66461456; called by muse, mutect2, varscan2
- BRINP2 | c.1996C>A p.L666M | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV64179749; called by muse, mutect2, varscan2
- C3orf20 | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV53784250; called by muse, varscan2
- C3orf22 | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145199781, COSV100559532, COSV59072856; called by muse, mutect2, varscan2
- C7 | c.1036G>T p.V346F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs369760989, COSV57479843; called by muse, mutect2, varscan2
- C8orf37 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120202, COSV54413642; called by muse, mutect2, varscan2
- CA3 | c.407A>C p.Q136P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV53411173; called by muse, mutect2
- CABS1 | c.215A>T p.K72M | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56734384, COSV56734515; called by muse, mutect2, varscan2
- CACNA1F | c.5396G>T p.R1799L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV104403432, COSV59906648; called by muse, mutect2, varscan2
- CACNA1F | c.5368C>T p.R1790C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs782100284, COSV59906651; called by muse, mutect2, varscan2
- CADPS | c.3047C>A p.P1016H | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV51899253; called by muse, mutect2, varscan2
- CADPS | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV51881247, COSV51882956, COSV51899273; called by muse, mutect2, varscan2
- CALB2 | c.93C>G p.D31E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV56941796; called by muse, mutect2, varscan2
- CARMIL3 | c.3871C>A p.Q1291K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.9); PolyPhen possibly damaging (0.692); catalogued as rs756849042, COSV53746160; called by muse, mutect2, varscan2
- CASK | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV59374191; called by muse, mutect2, varscan2
- CASP3 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57725696; called by muse, mutect2
- CBLN4 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs1387318827, COSV50354139; called by muse, mutect2, varscan2
- CCDC138 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV54571267; called by muse, mutect2, varscan2
- CCDC30 | c.1836G>T p.Q612H (on ENST00000340612; = p.Q569H on NM_001080850.3) | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59609025; called by muse, mutect2, varscan2
- CCDC93 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60123849; called by muse, mutect2, varscan2
- CCKAR | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55162652; called by muse, mutect2, varscan2
- CCT8L2 | c.620C>G p.A207G | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.339); catalogued as COSV63463644, COSV63463760; called by muse, mutect2, varscan2
- CDH11 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51775206; called by muse, mutect2, varscan2
- CDH18 | c.2117C>A p.T706N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.094); catalogued as COSV56955125; called by muse, mutect2, varscan2
- CDH19 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs750472640, COSV50973485; called by muse, mutect2, varscan2
- CDH7 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59884595, COSV59893215; called by muse, mutect2, varscan2
- CDH8 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100183523, COSV54895082; called by muse, mutect2, varscan2
- CDHR3 | c.2074A>T p.R692W | Missense Mutation (SNP) | VAF 360/482 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58421036; called by muse, mutect2, varscan2
- CELA1 | c.177G>T p.M59I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV53331575; called by muse, mutect2, varscan2
- CELA3A | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1323800968, COSV51586587; called by muse, mutect2, varscan2
- CELF2 | c.469C>A p.Q157K (on ENST00000416382 / NM_001025077.3; = p.Q164K on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.984); catalogued as COSV100257661; called by muse, mutect2, varscan2
- CELSR1 | c.5263G>T p.G1755C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53087180, COSV53098535; called by muse, mutect2, varscan2
- CELSR1 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53093081, COSV53098543; called by muse, mutect2, varscan2
- CEMIP | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.379); catalogued as COSV54999277, COSV54999979; called by muse, mutect2
- CEP164 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV54045697; called by muse, mutect2, varscan2
- CEP89 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 111/245 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs774924000; called by muse, mutect2, varscan2
- CFH | c.2730A>C p.E910D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.535); catalogued as COSV66412380; called by muse, mutect2, varscan2
- CFHR1 | c.395G>C p.R132P | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.707); catalogued as COSV57626247, COSV57626920, COSV57628831; called by muse, mutect2, varscan2
- CFHR2 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100804335; called by muse, varscan2
- CFP | c.1044G>T p.R348S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99901481; called by muse, mutect2, varscan2
- CHRM2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57782664; called by muse, mutect2, varscan2
- CHSY3 | c.1398G>C p.W466C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519082, COSV100519240; called by muse, mutect2, varscan2
- CIT | c.3557T>C p.L1186P | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV55880929; called by muse, mutect2, varscan2
- CLSPN | c.1794A>T p.K598N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52056347; called by muse, mutect2, varscan2
- CNGA4 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66006915; called by muse, mutect2, varscan2
- CNKSR2 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54264738; called by muse, mutect2, varscan2
- CNKSR2 | c.2799G>T p.M933I | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV65337701; called by muse, mutect2, varscan2
- CNNM1 | c.2028G>T p.Q676H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV63200752; called by muse, mutect2, varscan2
- CNTN3 | c.1142C>A p.S381Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); catalogued as COSV55182433; called by muse, mutect2, varscan2
- CNTN6 | c.2819T>A p.I940N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1474084517, COSV63186968; called by muse, mutect2, varscan2
- CNTNAP5 | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70508471; called by muse, mutect2, varscan2
- COG1 | c.2818dup p.A940Gfs*7 | Frame Shift Ins (INS) | VAF 27/76 reads (36%) | catalogued as COSV55429528; called by mutect2, pindel, varscan2
- COL11A1 | c.5283A>T p.K1761N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV62173940, COSV62195036; called by muse, mutect2, varscan2
- COL11A1 | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs557000127, COSV62195049; called by muse, mutect2
- COL1A1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56808905; called by muse, mutect2, varscan2
- COL22A1 | c.4543G>T p.G1515C | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57330275, COSV57356553; called by muse, mutect2, varscan2
- COL25A1 | c.473A>T p.Q158L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.982); catalogued as COSV67657216; called by muse, mutect2, varscan2
- COL3A1 | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV58595450; called by muse, mutect2, varscan2
- COL4A3 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.802); catalogued as COSV67419383; called by muse, mutect2, varscan2
- COL4A5 | c.3716C>A p.P1239H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.866); catalogued as COSV100087942, COSV60361949; called by muse, mutect2
- COL5A2 | c.2662G>C p.G888R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66414229; called by muse, mutect2, varscan2
- COL5A3 | c.2560-2A>G p.X854_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53418007; called by muse, mutect2, varscan2
- COL6A3 | c.1909A>G p.K637E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55106091; called by muse, mutect2, varscan2
- COL6A5 | c.7243G>T p.A2415S (on ENST00000312481; = p.A2411S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55214476; called by muse, mutect2, varscan2
- CPA1 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV50574364; called by muse, mutect2, varscan2
- CPA3 | c.1111A>T p.I371F | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772377917, COSV56047052; called by muse, mutect2, varscan2
- CPD | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV56715721; called by muse, mutect2, varscan2
- CPED1 | c.563A>C p.Q188P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV60011239; called by muse, mutect2, varscan2
- CREG2 | c.856G>T p.V286F | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs754794220, COSV61317509; called by muse, mutect2, varscan2
- CRIM1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54871290; called by muse, mutect2, varscan2
- CRX | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as COSV55759853; called by muse, mutect2, varscan2
- CSMD1 | c.1008C>A p.V336= | Splice Region (SNP) | VAF 8/48 reads (17%) | catalogued as COSV68250766; called by muse, mutect2, varscan2
- CSMD3 | c.7550G>T p.G2517V (on ENST00000297405 / NM_001363185.1; = p.G2413V on NM_052900.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52296351, COSV99830648; called by muse, mutect2, varscan2
- CSMD3 | c.5024A>T p.H1675L (on ENST00000297405 / NM_001363185.1; = p.H1571L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV52296369; called by muse, mutect2, varscan2
- CSMD3 | c.4460G>T p.G1487V (on ENST00000297405 / NM_001363185.1; = p.G1383V on NM_052900.3) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52296393; called by muse, mutect2, varscan2
- CSPP1 | c.1337+1G>T p.X446_splice (on ENST00000676605; = p.X405_splice on NM_024790.6) | Splice Site (SNP) | VAF 20/68 reads (29%) | catalogued as COSV51589836, COSV51591540; called by muse, varscan2
- CTCFL | c.1479T>A p.Y493* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | catalogued as rs150326376, COSV54778261; called by muse, mutect2, varscan2
- CTTNBP2 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 177/660 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50463082; called by muse, mutect2, varscan2
- CUBN | c.7088G>T p.C2363F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64725291; called by muse, mutect2, varscan2
- CUBN | c.1015+1G>T p.X339_splice | Splice Site (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100912012, COSV64725295; called by muse, mutect2, varscan2
- CUX2 | c.1784C>A p.P595H | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55645528; called by muse, mutect2, varscan2
- CWF19L2 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56519230; called by muse, mutect2
- CYBB | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV66086175; called by muse, mutect2, varscan2
- CYFIP2 | c.1829G>T p.G610V (on ENST00000616178 / NM_001291722.2; = p.G585V on NM_014376.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59049121; called by muse, mutect2, varscan2
- CYP2B6 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV57845239; called by muse, mutect2, varscan2
- DCC | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.414); catalogued as COSV59088461, COSV59129926; called by muse, mutect2, varscan2
- DCC | c.3899-2A>G p.X1300_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV71439805; called by muse, mutect2, varscan2
- DCDC1 | c.4381C>A p.P1461T (on ENST00000597505 / NM_001367979.1; = p.P568T on NM_020869.3) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100338351, COSV58000686; called by muse, mutect2
- DCDC1 | c.3157G>C p.D1053H (on ENST00000597505 / NM_001367979.1; = p.D160H on NM_020869.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV60311733; called by muse, mutect2, varscan2
- DCHS1 | c.4757C>T p.S1586F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV100201359, COSV55041666; called by muse, mutect2, varscan2
- DCXR | c.376G>T p.G126* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100178857; called by muse, mutect2, varscan2
- DEFB136 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66364045; called by muse, mutect2, varscan2
- DHTKD1 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV53806468; called by muse, mutect2, varscan2
- DHX29 | c.2848A>T p.R950* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV52421480; called by muse, mutect2, varscan2
- DHX30 | c.281C>T p.P94L (on ENST00000445061 / NM_138615.3; = p.P55L on NM_014966.3) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62396391; called by muse, mutect2, varscan2
- DIDO1 | c.4990C>T p.P1664S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs772648334, COSV56632763; called by mutect2, varscan2
- DISP3 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV53836108; called by muse, mutect2, varscan2
- DLGAP4 | c.2131C>T p.R711* (on ENST00000339266 / NM_001365621.1; = p.R708* on NM_014902.6) | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV59414030; called by muse, mutect2, varscan2
- DLK1 | c.1012C>A p.R338S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV57993211; called by muse, mutect2, varscan2
- DMRT3 | c.257T>G p.L86R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV51908051; called by muse, mutect2, varscan2
- DNAH1 | c.12223T>A p.W4075R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56239821; called by muse, mutect2
- DNAH8 | c.6157G>A p.D2053N | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59475637; called by muse, mutect2, varscan2
- DNAH9 | c.13053C>A p.N4351K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52372678; called by muse, mutect2, varscan2
- DNAJC10 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754190520, COSV51145312; called by muse, varscan2
- DNAJC5B | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as COSV99395654; called by muse, mutect2, varscan2
- DPP4 | c.458A>T p.Q153L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62109328; called by muse, mutect2, varscan2
- DSCAM | c.306C>A p.C102* | Nonsense Mutation (SNP) | VAF 38/141 reads (27%) | catalogued as COSV68652548; called by muse, mutect2, varscan2
- DSG2 | c.1093A>T p.R365W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV55202283; called by muse, mutect2, varscan2
- DTNA | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as COSV52022710; called by muse, mutect2
- DYRK4 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV50543922; called by muse, mutect2, varscan2
- ECM2 | c.1660C>A p.L554I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60742676; called by muse, mutect2, varscan2
- EDA | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV58878698; called by muse, mutect2, varscan2
- EMILIN2 | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV54426938; called by muse, mutect2, varscan2
- ENOX2 | c.143G>C p.G48A (on ENST00000338144 / NM_001382520.1; = p.G19A on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV57657241; called by muse, mutect2, varscan2
- EPAS1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV55385439; called by muse, mutect2, varscan2
- EPB41L2 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as COSV61358392; called by muse, mutect2, varscan2
- EPHA2 | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs754988701, COSV64454544, COSV64454984; called by muse, mutect2, varscan2
- EPPIN | c.392-1G>A p.X131_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100323220, COSV60548102; called by muse, mutect2, varscan2
- ERBB4 | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53520038, COSV53578775; called by muse, mutect2, varscan2
- ESS2 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52818633; called by muse, mutect2, varscan2
- EYS | c.1337G>T p.W446L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV60984396, COSV60998265; called by muse, mutect2, varscan2
- EZH1 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV70550491; called by muse, mutect2, varscan2
- EZH2 | c.1865C>A p.A622E (on ENST00000460911 / NM_001203247.2; = p.A627E on NM_004456.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100237310, COSV57461496; called by muse, mutect2, varscan2
- FAM120B | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.934); catalogued as COSV53007697; called by muse, mutect2, varscan2
- FAM126A | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV69472431; called by muse, mutect2, varscan2
- FAM47B | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV61456441; called by muse, mutect2, varscan2
- FASTKD5 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53908988, COSV99417691; called by muse, mutect2, varscan2
- FAT4 | c.10939G>A p.D3647N | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV58704857; called by muse, mutect2, varscan2
- FBN2 | c.4741C>A p.L1581M | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV52540876; called by muse, mutect2, varscan2
- FBN2 | c.1871C>G p.T624S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as COSV52540901; called by muse, mutect2, varscan2
- FKBP5 | c.293A>G p.K98R | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs769489554, COSV61883497; called by muse, mutect2, varscan2
- FLNA | c.6218G>C p.R2073P (on ENST00000369850 / NM_001110556.2; = p.R2065P on NM_001456.3) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100774751, COSV61045161; called by muse, mutect2, varscan2
- FMO4 | c.1248A>G p.K416= | Splice Region (SNP) | VAF 21/68 reads (31%) | catalogued as COSV63001855; called by muse, mutect2, varscan2
- FMR1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54426910; called by muse, mutect2
- FPGS | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV64676182; called by muse, varscan2
- FRAS1 | c.8014G>C p.D2672H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53641734; called by muse, mutect2, varscan2
- FRY | c.4039A>T p.T1347S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV66578041; called by muse, mutect2, varscan2
- FST | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 41/110 reads (37%) | catalogued as COSV56816709; called by muse, mutect2, varscan2
- GABRA6 | c.826+1G>T p.X276_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99194564; called by muse, mutect2, varscan2
- GABRB3 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs748359037, COSV54680853; called by muse, mutect2, varscan2
- GALNT5 | c.1714A>T p.R572W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52040650; called by muse, mutect2, varscan2
- GALNT7 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV53934086; called by muse, mutect2, varscan2
- GBA3 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72438157, COSV72438638; called by muse, mutect2, varscan2
- GCC2 | c.148+1G>C p.X50_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV59179498; called by muse, mutect2, varscan2
- GDF6 | c.1302C>A p.D434E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54627352; called by muse, mutect2, varscan2
- GJA1 | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as COSV56999291; called by muse, mutect2, varscan2
- GK2 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725971; called by muse, mutect2, varscan2
- GLI1 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.028); catalogued as COSV57366416; called by mutect2, varscan2
- GMCL1 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV99247768; called by muse, mutect2, varscan2
- GNG2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs139067662, COSV58915554; called by muse, mutect2, varscan2
- GPC4 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63699536; called by muse, mutect2, varscan2
- GPC4 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV63699541; called by muse, mutect2, varscan2
- GPC5 | c.1706C>A p.P569H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.946); catalogued as COSV65625032; called by muse, mutect2, varscan2
- GPD2 | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV60096306; called by muse, mutect2, varscan2
- GPR156 | c.723C>A p.Y241* | Nonsense Mutation (SNP) | VAF 28/137 reads (20%) | catalogued as COSV59942141; called by muse, mutect2, varscan2
- GPR158 | c.2276C>A p.T759K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66276097, COSV66280618; called by muse, mutect2, varscan2
- GPR52 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52321362; called by muse, mutect2, varscan2
- GPR78 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV101223987; called by muse, mutect2, varscan2
- GRIA3 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV52077861; called by muse, mutect2, varscan2
- GRID1 | c.275C>G p.T92R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV60023028, COSV60049340; called by muse, mutect2
- GUCY2F | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV54307523; called by muse, mutect2, varscan2
- GUCY2F | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 106/362 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54307538; called by muse, mutect2, varscan2
- HBB | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV58943056; called by muse, mutect2, varscan2
- HCFC1 | c.3131C>A p.T1044N | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV60076871; called by muse, mutect2
- HDAC2 | c.283+1G>T p.X95_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100892634; called by muse, varscan2
- HDAC6 | c.317C>G p.P106R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781865210, COSV100491400, COSV61930390; called by muse, mutect2, varscan2
- HDX | c.1439G>T p.C480F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99947388; called by muse, mutect2, varscan2
- HEPH | c.1360G>T p.G454* (on ENST00000343002; = p.G187* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV57970764; called by muse, mutect2, varscan2
- HEPN1 | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs1555053831, COSV100005736; called by muse, mutect2, varscan2
- HERPUD2 | c.139A>G p.S47G | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV60946989; called by muse, mutect2, varscan2
- HNF4A | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV57388445; called by muse, mutect2, varscan2
- HSPA13 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV53465090; called by muse, mutect2, varscan2
- IFT122 | c.3697C>T p.R1233C (on ENST00000348417 / NM_052989.3; = p.R1174C on NM_018262.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs778449955, COSV56201885; called by muse, mutect2, varscan2
- IGDCC4 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100732926; called by muse, mutect2, varscan2
- IGDCC4 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.495); catalogued as COSV100732591; called by muse, mutect2, varscan2
- IGKV6D-41 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs772221263; called by muse, mutect2, varscan2
- IGSF1 | c.3034C>T p.Q1012* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as CM164155, COSV63839838; called by muse, mutect2, varscan2
- IKZF2 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59583252; called by muse, mutect2, varscan2
- IL16 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV57262153, COSV57267595; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.039); catalogued as COSV61178189; called by muse, mutect2, varscan2
- IL20RB | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs748169333, COSV59049349; called by muse, mutect2, varscan2
- IL21R | c.604del p.A202Qfs*29 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as CM131799, CM151346; called by mutect2, pindel, varscan2
- IL21R | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); catalogued as COSV61970545, COSV61972311; called by muse, mutect2, varscan2
- INSC | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV65412812; called by muse, mutect2, varscan2
- IRF6 | c.31A>T p.K11* | Nonsense Mutation (SNP) | VAF 43/119 reads (36%) | catalogued as CM1010271, COSV65420300; called by muse, mutect2, varscan2
- ISX | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58085634; called by muse, mutect2, varscan2
- ITGAD | c.986A>T p.Q329L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV66759865; called by muse, mutect2, varscan2
- ITGAD | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV66759870; called by muse, mutect2, varscan2
- ITPKB | c.1702G>C p.A568P | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55268189; called by muse, mutect2, varscan2
- IZUMO1R | c.543G>T p.K181N (on ENST00000440961; = p.K188N on NM_001199206.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV60623433; called by muse, mutect2, varscan2
- KCNA4 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs749396985, COSV100068726, COSV60251043; called by muse, mutect2, varscan2
- KCND2 | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 385/492 reads (78%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV58600030; called by muse, mutect2, varscan2
- KCNJ12 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59172708; called by muse, mutect2
- KCNJ4 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV57858528, COSV57859077; called by muse, mutect2, varscan2
- KCNK18 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV57972075; called by muse, mutect2, varscan2
- KCNQ4 | c.1928G>T p.C643F | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.958); catalogued as rs1311054891, COSV61275376; called by muse, mutect2, varscan2
- KDR | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.218); catalogued as COSV55774443; called by muse, mutect2, varscan2
- KEAP1 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50638306; called by muse, mutect2, varscan2
- KIAA0100 | c.4300G>T p.E1434* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV66495903; called by muse, mutect2, varscan2
- KIF1B | c.4852G>T p.D1618Y (on ENST00000377086 / NM_001365952.1; = p.D1572Y on NM_015074.3) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV55815096; called by muse, mutect2, varscan2
- KIF26B | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV69470814; called by muse, mutect2, varscan2
- KIF26B | c.2482A>T p.T828S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV63650355; called by muse, mutect2, varscan2
- KIF2B | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV52132214; called by muse, mutect2, varscan2
- KL | c.430del p.V144Sfs*155 | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | catalogued as COSV101199168; called by mutect2, pindel, varscan2
- KLF8 | c.1021C>A p.R341S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100808261; called by muse, mutect2
- KRT6B | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV99360769; called by muse, mutect2, varscan2
- KRT6B | c.891C>A p.F297L | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99360771; called by muse, mutect2, varscan2
- KRT75 | c.1464C>A p.S488R | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as COSV52875037; called by muse, mutect2, varscan2
- KRTAP26-1 | c.386T>A p.L129H | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as COSV100860424; called by muse, mutect2, varscan2
- KRTAP4-4 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66811509; called by muse, mutect2, varscan2
- LDHAL6A | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV55009248; called by muse, mutect2, varscan2
- LGR5 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57009222; called by muse, mutect2, varscan2
- LHFPL3 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV67818771; called by muse, varscan2
- LIFR | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV54698182; called by muse, mutect2, varscan2
- LILRB5 | c.1122T>A p.Y374* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as rs778335452, COSV60260584, COSV60261403; called by muse, mutect2, varscan2
- LIN37 | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as rs754704937, COSV50001208; called by muse, mutect2, varscan2
- LINS1 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59080332, COSV59080766; called by muse, mutect2, varscan2
- LIPK | c.767G>T p.S256I | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV68201740; called by muse, mutect2, varscan2
- LNX1 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV55790822; called by muse, mutect2, varscan2
- LRIT2 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV60565921; called by muse, mutect2, varscan2
- LRP1 | c.4736A>G p.Y1579C | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV54523826; called by muse, mutect2, varscan2
- LRP1 | c.13625C>T p.P4542L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54523842, COSV99674801; called by muse, mutect2, varscan2
- LRP1B | c.7650A>T p.R2550S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67266529; called by muse, mutect2, varscan2
- LRRC52 | c.716A>T p.H239L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV54233477; called by muse, mutect2, varscan2
- LRRC7 | c.3878C>A p.T1293N (on ENST00000651989 / NM_001370785.2; = p.T1260N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV50603156; called by muse, mutect2, varscan2
- LRRIQ1 | c.4937G>C p.S1646T | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as rs1298908121, COSV67837313; called by muse, mutect2, varscan2
- LZTR1 | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 393/439 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1417500183, COSV53144822; called by muse, mutect2, varscan2
- MADD | c.4592C>T p.A1531V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV60629204; called by muse, mutect2, varscan2
- MAGEA4 | c.645C>A p.D215E | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99367518; called by muse, mutect2
- MAGEB4 | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100974991; called by muse, mutect2, varscan2
- MAGEC1 | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 95/608 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53578071; called by muse, varscan2
- MAP3K2 | c.1102G>C p.G368R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61295957; called by muse, mutect2
- MAPK10 | c.154G>T p.V52L (on ENST00000359221 / NM_001351625.2; = p.V90L on NM_002753.5) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV60392227; called by muse, mutect2, varscan2
- MARK2 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 44/91 reads (48%) | catalogued as COSV59287106, COSV59288411; called by muse, mutect2, varscan2
- MCHR2 | c.390C>T p.D130= | Splice Region (SNP) | VAF 66/175 reads (38%) | catalogued as rs1223853922, COSV56007774; called by muse, mutect2, varscan2
- MCM4 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50631289; called by muse, mutect2, varscan2
- MCTP2 | c.2296G>C p.D766H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63296888, COSV63297588; called by muse, mutect2, varscan2
- MDGA2 | c.1001T>A p.V334D (on ENST00000399232 / NM_001113498.2; = p.V36D on NM_182830.4) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.726); catalogued as COSV62112536; called by muse, mutect2
- MEGF6 | c.489C>G p.D163E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53895144; called by muse, mutect2, varscan2
- MEPE | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as COSV63074273; called by muse, mutect2, varscan2
- MFSD1 | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV51842913; called by muse, mutect2, varscan2
- MGAM | c.2657T>C p.I886T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV72075561; called by muse, mutect2, varscan2
- MGAT4A | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53847389; called by muse, mutect2, varscan2
- MGST1 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV50567424, COSV99163197; called by muse, mutect2, varscan2
- MIF4GD | c.505C>A p.R169S (on ENST00000325102 / NM_001370592.1; = p.R203S on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs749267112, COSV55453798, COSV99821596; called by muse, mutect2, varscan2
- MIS18A | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV51590385; called by muse, mutect2, varscan2
- MME | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100852414; called by muse, mutect2, varscan2
- MRGPRX3 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); catalogued as COSV66934730; called by muse, mutect2
- MTCL1 | c.1899G>T p.E633D (on ENST00000306329 / NM_001378206.1; = p.E273D on NM_015210.4) | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60410973; called by muse, mutect2, varscan2
- MTCP1 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62899974, COSV62900503; called by muse, mutect2, varscan2
- MUC16 | c.27168C>A p.D9056E | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.327); catalogued as COSV67488861; called by muse, mutect2, varscan2
- MUC16 | c.14503G>T p.V4835L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.11); catalogued as COSV67488863; called by muse, mutect2, varscan2
- MXRA5 | c.8240C>A p.P2747H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54247860; called by muse, mutect2, varscan2
- MXRA5 | c.3340G>T p.E1114* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV54247904; called by muse, mutect2, varscan2
- MYF6 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57350655; called by muse, mutect2
- MYH2 | c.3907C>G p.L1303V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as COSV55436328, COSV55441585; called by muse, mutect2, varscan2
- MYL4 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100733126; called by muse, mutect2, varscan2
- MYO9B | c.1867G>C p.G623R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as COSV68282380; called by muse, mutect2, varscan2
- NAIF1 | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.901); catalogued as COSV66092237; called by muse, mutect2, varscan2
- NALCN | c.1317T>A p.C439* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as COSV51960979; called by muse, mutect2, varscan2
- NAV3 | c.6253G>T p.A2085S (on ENST00000397909 / NM_001024383.2; = p.A2063S on NM_014903.6) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.654); catalogued as COSV57085236, COSV57107954; called by muse, mutect2, varscan2
- NCOR2 | c.5644G>T p.G1882C | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62303302; called by muse, mutect2, varscan2
- NCOR2 | c.3232G>T p.A1078S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.108); catalogued as COSV100657399, COSV62297949; called by muse, mutect2, varscan2
- NECAB1 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101341091, COSV70243676; called by muse, mutect2, varscan2
- NEDD4 | c.2538G>T p.W846C (on ENST00000508342 / NM_001284338.1; = p.W427C on NM_006154.4) | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100163771; called by muse, mutect2, varscan2
- NEDD4 | c.2537G>T p.W846L (on ENST00000508342 / NM_001284338.1; = p.W427L on NM_006154.4) | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100163772; called by muse, mutect2, varscan2
- NELFCD | c.853G>C p.A285P (on ENST00000602795; = p.A267P on NM_198976.4) | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV53883651, COSV53884649; called by muse, mutect2, varscan2
- NF1 | c.5444A>T p.Q1815L (on ENST00000358273 / NM_001042492.3; = p.Q1794L on NM_000267.3) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV62218188; called by muse, mutect2, varscan2
- NLGN4X | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as COSV52033941; called by muse, mutect2, varscan2
- NLRP13 | c.791A>T p.Y264F | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs776218787, COSV61623813; called by muse, mutect2, varscan2
- NLRP14 | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55071295; called by muse, mutect2, varscan2
- NLRP3 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60230209; called by muse, mutect2, varscan2
- NOC2L | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs3828050, COSV58990546; called by muse, mutect2, varscan2
- NOL4 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV52359638, COSV52367107; called by muse, mutect2, varscan2
- NOTCH4 | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV66683441; called by muse, mutect2, varscan2
- NPAP1 | c.2716G>T p.G906W | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV61505137; called by muse, mutect2, varscan2
- NPR2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV61314231; called by muse, mutect2, varscan2
- NPY5R | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV58453644; called by muse, mutect2, varscan2
- NR1I2 | c.795-1G>T p.X265_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as COSV61979366, COSV61979543; called by muse, mutect2, varscan2
- NRXN1 | c.2415T>A p.N805K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58456167, COSV58486523; called by muse, mutect2, varscan2
- NRXN1 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.537); catalogued as COSV101277647, COSV68006313; called by muse, mutect2, varscan2
- NTNG1 | c.1166A>T p.H389L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV64273648, COSV64278211; called by muse, mutect2, varscan2
- NUP153 | c.145A>G p.N49D | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV50462495; called by muse, mutect2
- NUP205 | c.4681A>T p.T1561S | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV53665088; called by muse, mutect2
- NUP210 | c.5459G>T p.G1820V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV54412820; called by muse, mutect2, varscan2
- NXT2 | c.422G>T p.S141I (on ENST00000372106 / NM_001242617.2; = p.S196I on NM_018698.5) | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV54296704; called by muse, mutect2, varscan2
- NYX | c.860G>C p.R287P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61180475, COSV61181643; called by muse, mutect2, varscan2
- OPRL1 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61092707; called by muse, mutect2, varscan2
- OPRM1 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57684232; called by muse, mutect2, varscan2
- OR10Q1 | c.847T>A p.Y283N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57471829; called by muse, mutect2, varscan2
- OR13C8 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs773921698, COSV58611789, COSV58612274; called by muse, mutect2, varscan2
- OR13C8 | c.359T>A p.L120Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV58612283; called by muse, mutect2, varscan2
- OR13F1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100594776; called by muse, mutect2, varscan2
- OR1Q1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52918939; called by muse, mutect2, varscan2
- OR2A7 | c.520T>A p.Y174N | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101512217; called by muse, mutect2, varscan2
- OR2C3 | c.629T>A p.L210Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63576048; called by muse, mutect2, varscan2
- OR2D3 | c.923T>G p.L308W | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53494639; called by muse, mutect2, varscan2
- OR2T33 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58817582; called by muse, varscan2
- OR2W1 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.824); catalogued as rs746974366, COSV65851859; called by muse, mutect2, varscan2
- OR4A15 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as rs773785451, COSV59034778, COSV59037378; called by muse, mutect2, varscan2
- OR4A47 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV71445122; called by muse, mutect2, varscan2
- OR4A5 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.013); catalogued as COSV60524357; called by muse, varscan2
- OR4C6 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV58604599; called by muse, mutect2, varscan2
- OR4K13 | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV59860640; called by muse, mutect2, varscan2
- OR51Q1 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs754720163, COSV56180367; called by muse, mutect2, varscan2
- OR52E8 | c.843A>T p.L281F | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV66211578; called by muse, mutect2, varscan2
- OR52M1 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV64172610; called by muse, mutect2
- OR5B12 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56906503; called by muse, mutect2, varscan2
- OR5B3 | c.903A>T p.K301N | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.167); catalogued as COSV58678486; called by muse, mutect2
- OR5D14 | c.880C>A p.L294I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1248689922, COSV59458205, COSV59459255; called by muse, mutect2
- OR5K1 | c.384C>A p.N128K | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV60305204; called by muse, mutect2, varscan2
- OR5K4 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs757150081, COSV100721357; called by muse, mutect2, varscan2
- OR5L2 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV65723460, COSV65724594, COSV65724996; called by muse, mutect2, varscan2
- OR5M8 | c.392A>T p.Y131F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762469193, COSV59118031; called by muse, mutect2, varscan2
- OR6B3 | c.214T>A p.W72R | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100097303, COSV60112835; called by muse, mutect2, varscan2
- PABPC5 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57042935; called by muse, mutect2, varscan2
- PAM | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99173566; called by muse, mutect2, varscan2
- PAOX | c.1472G>T p.R491M | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53374442; called by muse, mutect2, varscan2
- PARP8 | c.1576-1G>T p.X526_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as COSV55865999; called by muse, mutect2, varscan2
- PASD1 | c.1036T>A p.S346T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as COSV64857348; called by muse, mutect2, varscan2
- PAX4 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV58391017; called by muse, mutect2
- PBX2 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100904011; called by muse, mutect2, varscan2
- PBX2 | c.544-1G>T p.X182_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100904012; called by muse, mutect2, varscan2
- PCDH11X | c.3404C>A p.A1135D | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100011077, COSV53498694; called by muse, mutect2, varscan2
- PCDH15 | c.4621G>T p.E1541* (on ENST00000644397 / NM_001354429.2; = p.E1490* on NM_001142769.3) | Nonsense Mutation (SNP) | VAF 9/152 reads (6%) | catalogued as COSV64728762; called by muse, mutect2
- PCDH8 | c.2061G>T p.R687S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV58814842; called by muse, mutect2, varscan2
- PCDHGA5 | c.1270G>C p.V424L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV54017918; called by muse, mutect2, varscan2
- PCDHGA6 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53895537, COSV54017956; called by muse, mutect2, varscan2
- PCLO | c.12411G>T p.E4137D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as COSV61660897, COSV61667126; called by muse, mutect2, varscan2
- PDCD6IP | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56245335; called by muse, mutect2, varscan2
- PDE4B | c.1628T>A p.V543D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303816; called by muse, mutect2, varscan2
- PDE9A | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99371640; called by muse, mutect2
- PDPN | c.266C>G p.T89R (on ENST00000621990; = p.T165R on NM_006474.4) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53850707; called by muse, mutect2, varscan2
- PDZD7 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100931637, COSV99058726; called by muse, mutect2, varscan2
- PDZD8 | c.1918G>T p.D640Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100559562, COSV57825338; called by muse, mutect2, varscan2
- PELI2 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV50715381; called by muse, mutect2, varscan2
- PHLDB1 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs782158592, COSV61881527; called by muse, mutect2
- PIK3R4 | c.2500G>T p.V834F | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.068); catalogued as rs151220675, COSV63243144; called by muse, mutect2
- PIK3R5 | c.207C>A p.V69= | Splice Region (SNP) | VAF 5/11 reads (45%) | catalogued as COSV52658046; called by muse, mutect2, varscan2
- PITPNM3 | c.2398A>T p.N800Y | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52599330; called by muse, mutect2, varscan2
- PKHD1 | c.3983T>A p.V1328D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV61891993; called by muse, mutect2, varscan2
- PKHD1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV61892009; called by muse, mutect2, varscan2
- PLA2G2A | c.373T>A p.Y125N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64287604; called by muse, mutect2, varscan2
- PLPPR4 | c.1765C>A p.L589I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.804); catalogued as COSV64567520; called by muse, mutect2, varscan2
- PLPPR5 | c.465T>A p.C155* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV54177801; called by muse, mutect2, varscan2
- PLXNA4 | c.5063T>G p.L1688R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58155646; called by muse, mutect2
- PLXNA4 | c.1722C>A p.N574K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs759386370, COSV58117902, COSV58155656; called by muse, mutect2, varscan2
- PNKD | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV51239725; called by muse, mutect2, varscan2
- POGLUT2 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV65683541; called by muse, mutect2, varscan2
- POM121L12 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV68693472; called by muse, mutect2, varscan2
- PPFIA2 | c.2335C>A p.P779T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61046657, COSV61050843; called by muse, mutect2, varscan2
- PPP2R3B | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as COSV66814302; called by muse, mutect2, varscan2
- PPP6R1 | c.1873G>T p.E625* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV69800628; called by muse, mutect2, varscan2
- PRDM11 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99770767; called by muse, mutect2, varscan2
- PRDM5 | c.215A>T p.D72V | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53366207; called by muse, mutect2
- PRKCG | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.262); catalogued as COSV54732143; called by muse, mutect2, varscan2
- PRSS37 | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1240259192, COSV63340037; called by muse, mutect2, varscan2
- PSMD10 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV54263848, COSV99480692; called by muse, mutect2, varscan2
- PTCHD1 | c.2638C>A p.R880S | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as COSV101037745; called by muse, mutect2, varscan2
- PXDNL | c.915C>A p.C305* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV62497034; called by muse, mutect2, varscan2
- RAB6C | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV101308512; called by mutect2, varscan2
- RAPGEF2 | c.2516A>T p.D839V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52433016; called by muse, mutect2, varscan2
- RGS3 | c.783G>T p.E261D (on ENST00000350696 / NM_001282923.2; = p.E149D on NM_017790.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100465373; called by muse, mutect2
- RHBDL1 | c.1060G>T p.G354C (on ENST00000219551 / NM_001318733.2; = p.G289C on NM_001278720.2) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99555643, COSV99555755; called by muse, mutect2
- RHEB | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100062140; called by muse, mutect2, varscan2
- RHEB | c.193-1G>T p.X65_splice | Splice Site (SNP) | VAF 29/131 reads (22%) | catalogued as COSV100062144; called by muse, mutect2, varscan2
- RNF2 | c.157A>T p.I53F | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62280396; called by muse, mutect2, varscan2
- RNF44 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.472); catalogued as COSV51271044, COSV51271119; called by muse, mutect2, varscan2
- RORB | c.1143A>G p.P381= (on ENST00000396204 / NM_001365023.1; = p.P370= on NM_006914.4) | Splice Region (SNP) | VAF 7/95 reads (7%) | catalogued as COSV65339454; called by muse, mutect2
- RP1 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55125046; called by muse, mutect2, varscan2
- RP1L1 | c.5626G>T p.A1876S | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs199697887, COSV66759441; called by muse, mutect2, varscan2
- RP1L1 | c.4424C>T p.P1475L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.109); catalogued as COSV66759448; called by muse, mutect2, varscan2
- RP1L1 | c.3011G>T p.G1004V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV101223292; called by muse, mutect2, varscan2
- RPL10L | c.70del p.R24Efs*54 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as COSV53559245; called by mutect2, pindel, varscan2
- RREB1 | c.2221G>C p.A741P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV58564118; called by muse, mutect2, varscan2
- RSPH6A | c.1917A>G p.K639= | Splice Region (SNP) | VAF 30/140 reads (21%) | catalogued as COSV54291665; called by muse, mutect2, varscan2
- RTN3 | c.1674G>T p.L558F (on ENST00000377819 / NM_001265589.2; = p.L539F on NM_201428.3) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100380201; called by muse, mutect2, varscan2
- RUFY2 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV61192226; called by muse, mutect2, varscan2
- RYR3 | c.6561G>T p.W2187C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482878634, COSV101212896; called by muse, mutect2, varscan2
- RYR3 | c.6747G>C p.K2249N | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV63109795; called by muse, mutect2, varscan2
- SASS6 | c.233T>G p.V78G | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54929995; called by muse, mutect2
- SATL1 | c.645C>A p.S215R (on ENST00000395409; = p.S402R on NM_001012980.2) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV60578177; called by muse, mutect2
- SCN1A | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 69/347 reads (20%) | catalogued as COSV57684628; called by muse, mutect2, varscan2
- SCN9A | c.4420A>T p.M1474L (on ENST00000303354; = p.M1463L on NM_002977.3) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV57621898; called by muse, mutect2, varscan2
- SCN9A | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV57621916; called by muse, mutect2, varscan2
- SEC24B | c.3368G>T p.R1123M | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54505465; called by muse, mutect2, varscan2
- SEMA5B | c.3297+1G>C p.X1099_splice | Splice Site (SNP) | VAF 34/60 reads (57%) | catalogued as COSV52106746; called by muse, mutect2, varscan2
- SEMA6D | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs201871061, COSV60382811; called by muse, mutect2, varscan2
- SERPINA9 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54077612; called by muse, mutect2, varscan2
- SERPINB12 | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.197); catalogued as COSV54034745; called by muse, mutect2, varscan2
- SETD2 | c.4552G>T p.E1518* | Nonsense Mutation (SNP) | VAF 54/128 reads (42%) | catalogued as COSV57448953; called by muse, mutect2, varscan2
- SF1 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 84/146 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV57116965; called by muse, mutect2, varscan2
- SFTPB | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as rs1427648151, CD993070, COSV60894184; called by muse, mutect2, varscan2
- SH2D4A | c.775A>T p.R259W | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56124597; called by muse, mutect2, varscan2
- SH3BP2 | c.307A>C p.K103Q | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV62555215; called by muse, mutect2, varscan2
- SH3GL2 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV66054501; called by muse, mutect2, varscan2
- SHANK1 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV53260510; called by muse, mutect2, varscan2
- SHISA2 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100096437, COSV60111542; called by muse, mutect2, varscan2
- SIRPG | c.420G>T p.M140I | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1211510692, COSV53809899; called by muse, mutect2, varscan2
- SLC14A2 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV54913915; called by muse, mutect2, varscan2
- SLC15A3 | c.844G>C p.A282P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.229); catalogued as COSV57173140; called by muse, mutect2, varscan2
- SLC30A2 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV65333267; called by muse, mutect2, varscan2
- SLC34A2 | c.1264G>T p.V422F | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV65942913; called by muse, mutect2, varscan2
- SLC38A1 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101284208; called by muse, mutect2, varscan2
- SLC39A12 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as rs374008416, COSV66202024; called by muse, mutect2, varscan2
- SLC39A12 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV66195265, COSV66202031; called by muse, mutect2, varscan2
- SLC43A2 | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as COSV100025004; called by muse, mutect2, varscan2
- SLC6A15 | c.1631T>A p.V544E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57028806; called by muse, mutect2, varscan2
- SLC9A6 | c.1445C>A p.T482K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65788897; called by muse, mutect2, varscan2
- SLITRK1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV65677264; called by muse, mutect2, varscan2
- SMARCA2 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV61811678; called by muse, mutect2, varscan2
- SMARCA4 | c.3247G>T p.E1083* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | catalogued as COSV60793423, COSV60808862; called by muse, mutect2, varscan2
- SMC2 | c.3505G>T p.A1169S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53963863; called by muse, mutect2, varscan2
- SNAI2 | c.453C>G p.C151W | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV50078629, COSV50080015; called by muse, mutect2, varscan2
- SNRNP200 | c.4310G>T p.R1437L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60493920; called by muse, mutect2, varscan2
- SNRNP70 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV55507111; called by muse, mutect2, varscan2
- SNX5 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.316); catalogued as COSV66698522; called by muse, mutect2, varscan2
- SORCS3 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV63822058; called by muse, mutect2, varscan2
- SOS2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53567505; called by muse, mutect2, varscan2
- SOWAHB | c.1005C>A p.F335L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV57555119; called by muse, mutect2, varscan2
- SPATA31D1 | c.4188T>A p.F1396L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV61200403; called by muse, mutect2, varscan2
- SPHKAP | c.2807C>G p.T936R | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60891891; called by muse, mutect2, varscan2
- SPIRE1 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59161714; called by muse, mutect2, varscan2
- ST8SIA6 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 47/167 reads (28%) | catalogued as COSV66467456; called by muse, mutect2, varscan2
- STAB2 | c.5397C>A p.F1799L | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV66345744; called by muse, mutect2, varscan2
- STAG2 | c.3100A>T p.R1034* | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as COSV54370775; called by muse, mutect2, varscan2
- STK17B | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV55829927; called by muse, mutect2, varscan2
- STON1 | c.1894G>T p.V632L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV59136831; called by muse, mutect2, varscan2
- SUN1 | c.655A>T p.K219* (on ENST00000405266 / NM_001367651.1; = p.K169* on NM_025154.6 and 13 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/394 reads (7%) | catalogued as COSV61779181; called by muse, mutect2
- SUSD2 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV64202743; called by muse, mutect2, varscan2
- TAF1L | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.241); catalogued as rs761229672, COSV54267831; called by muse, mutect2, varscan2
- TENM3 | c.1567C>A p.H523N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as COSV69317417; called by muse, mutect2, varscan2
- TEP1 | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 70/244 reads (29%) | catalogued as COSV52998874; called by muse, mutect2, varscan2
- TET1 | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1234170961, COSV65388833; called by muse, mutect2, varscan2
- TFCP2L1 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV55290833; called by muse, mutect2, varscan2
- THADA | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV57691883; called by muse, mutect2, varscan2
- THSD7A | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV70271284; called by muse, mutect2, varscan2
- THSD7B | c.2885del p.G962Afs*7 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as COSV55703197; called by mutect2, pindel, varscan2
- TLN2 | c.2489G>T p.R830L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60894855; called by muse, mutect2, varscan2
- TLR8 | c.693C>G p.N231K (on ENST00000218032 / NM_138636.5; = p.N249K on NM_016610.4) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV54320193; called by muse, mutect2, varscan2
- TMEM202 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as rs368153584, COSV100499222; called by muse, mutect2, varscan2
- TMEM51 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV101051537; called by muse, mutect2, varscan2
- TMIGD2 | c.713C>A p.S238* | Nonsense Mutation (SNP) | VAF 25/49 reads (51%) | catalogued as COSV56668005, COSV56668490; called by muse, mutect2, varscan2
- TMPRSS11F | c.163+2T>C p.X55_splice | Splice Site (SNP) | VAF 37/95 reads (39%) | catalogued as COSV62468971; called by muse, mutect2, varscan2
- TNMD | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs377645140, COSV65977721; called by mutect2, varscan2
- TPK1 | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV63646899; called by muse, mutect2, varscan2
- TRIM17 | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.299); catalogued as COSV52859782; called by muse, mutect2, varscan2
- TRMT44 | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV67664829; called by muse, mutect2, varscan2
- TRO | c.815C>A p.T272N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99436547; called by mutect2, varscan2
- TRPC6 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 74/125 reads (59%) | catalogued as COSV60259887; called by muse, mutect2, varscan2
- TRPS1 | c.2579G>T p.G860V (on ENST00000220888 / NM_001330599.2; = p.G873V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV55250809; called by muse, mutect2, varscan2
- TSC1 | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV53772204; called by muse, mutect2, varscan2
- TSHZ2 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61586704, COSV61591051; called by muse, mutect2, varscan2
- TSLP | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61292314; called by muse, mutect2, varscan2
- TSNAXIP1 | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV101183906; called by muse, mutect2, varscan2
- TTN | c.91754C>A p.P30585Q (on ENST00000591111; = p.P23161Q on NM_003319.4) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | PolyPhen probably damaging (1); catalogued as COSV60297845; called by muse, mutect2, varscan2
- TTN | c.87839C>G p.T29280R (on ENST00000591111; = p.T21856R on NM_003319.4) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | PolyPhen benign (0.203); catalogued as COSV60297882; called by muse, mutect2, varscan2
- TTN | c.72994C>A p.Q24332K (on ENST00000591111; = p.Q16908K on NM_003319.4) | Missense Mutation (SNP) | VAF 51/196 reads (26%) | PolyPhen benign (0.001); catalogued as COSV60297920; called by muse, mutect2, varscan2
- TTN | c.71540G>T p.G23847V (on ENST00000591111; = p.G16423V on NM_003319.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | PolyPhen probably damaging (1); catalogued as COSV60297957; called by muse, mutect2, varscan2
- TTN | c.17698G>T p.E5900* (on ENST00000591111; = p.E4973* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | catalogued as COSV60165836, COSV60297992; called by muse, mutect2, varscan2
- TTYH2 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53913003; called by muse, mutect2
- TVP23C | c.704A>C p.Q235P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.72); catalogued as COSV56669391, COSV56673088; called by muse, varscan2
- TXLNB | c.1093G>T p.G365* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV64445411; called by muse, mutect2, varscan2
- UBASH3A | c.1654C>A p.L552I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764697571, COSV52315563; called by muse, mutect2, varscan2
- UBR5 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 70/167 reads (42%) | catalogued as COSV55290778; called by muse, mutect2, varscan2
- UGT2B28 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as COSV59432324; called by muse, mutect2, varscan2
- UGT2B28 | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV100158840; called by muse, mutect2, varscan2
- UNC13C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as COSV52916635; called by muse, varscan2
- UNC13D | c.753+1G>A p.X251_splice | Splice Site (SNP) | VAF 34/81 reads (42%) | catalogued as rs201908137, CS033138, COSV52886978; called by muse, mutect2, varscan2
- USH2A | c.7930T>A p.W2644R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56424361; called by muse, mutect2, varscan2
- USH2A | c.6175G>T p.V2059F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767444125, COSV56424381; called by muse, varscan2
- USP11 | c.2557G>T p.D853Y (on ENST00000218348; = p.D810Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54475685; called by muse, mutect2, varscan2
- USP38 | c.2587A>T p.R863W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61027241; called by muse, mutect2, varscan2
- UTP20 | c.5165A>G p.D1722G | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV55384342; called by muse, mutect2, varscan2
- VNN1 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.026); catalogued as COSV63390874; called by muse, mutect2, varscan2
- VPREB1 | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV56426208; called by muse, mutect2, varscan2
- VPS13D | c.1874G>C p.R625P | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62533798; called by muse, mutect2, varscan2
- VSIG2 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1273625428, COSV52519391; called by muse, mutect2, varscan2
- VWA3B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772865808, COSV68246164; called by muse, mutect2
- VWA7 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV65174051; called by muse, mutect2, varscan2
- WBP4 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329626858, COSV101069280; called by muse, mutect2
- WRN | c.264A>T p.L88F | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV53306246; called by muse, mutect2, varscan2
- WWC1 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV54657595; called by muse, mutect2, varscan2
- XIRP2 | c.8917G>A p.D2973N (on ENST00000628543; = p.D3148N on NM_152381.6) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV54729691; called by muse, mutect2, varscan2
- XPOT | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV60347708; called by muse, mutect2, varscan2
- YME1L1 | c.67T>A p.F23I | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as COSV58761261; called by muse, mutect2
- ZBTB25 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV101170732; called by muse, mutect2, varscan2
- ZC3H13 | c.1428G>T p.M476I | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV54462048; called by muse, mutect2
- ZEB2 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57965037; called by muse, mutect2, varscan2
- ZFAND1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV55108456; called by muse, mutect2, varscan2
- ZFHX3 | c.3875C>G p.P1292R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs770124724, COSV51732886; called by muse, mutect2, varscan2
- ZFHX4 | c.4042C>A p.Q1348K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.15); catalogued as rs748248986, COSV99263390; called by muse, mutect2, varscan2
- ZFP14 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV99525180; called by muse, mutect2
- ZIC1 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV51557295; called by muse, mutect2, varscan2
- ZNF133 | c.1673G>T p.G558V (on ENST00000316358 / NM_001352454.2; = p.G557V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315524; called by muse, mutect2, varscan2
- ZNF135 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV57882593, COSV57885341; called by muse, mutect2, varscan2
- ZNF138 | c.870G>T p.Q290H (on ENST00000307355 / NM_001367572.1; = p.Q264H on NM_006524.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100245781; called by muse, mutect2, varscan2
- ZNF155 | c.1571G>C p.R524P | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as COSV54208250, COSV99525771; called by muse, mutect2, varscan2
- ZNF208 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760097530, COSV68102124, COSV68111716; called by muse, mutect2, varscan2
- ZNF287 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 74/152 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV67689042; called by muse, mutect2, varscan2
- ZNF33A | c.1409G>A p.C470Y (on ENST00000458705 / NM_006974.3; = p.C471Y on NM_006954.2) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757188582, COSV56727375; called by mutect2, varscan2
- ZNF398 | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60066523; called by muse, mutect2, varscan2
- ZNF423 | c.3107C>A p.T1036K (on ENST00000563137 / NM_001379286.1; = p.T1028K on NM_015069.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52202138; called by mutect2, varscan2
- ZNF423 | c.2675C>A p.P892H (on ENST00000563137 / NM_001379286.1; = p.P884H on NM_015069.4) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52202146; called by muse, mutect2, varscan2
- ZNF45 | c.2008G>C p.D670H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV54194434; called by muse, mutect2, varscan2
- ZNF461 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV64454997; called by muse, mutect2, varscan2
- ZNF536 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62824937, COSV62832875; called by muse, mutect2, varscan2
- ZNF543 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100386798; called by muse, mutect2, varscan2
- ZNF546 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV61259338; called by muse, mutect2, varscan2
- ZNF572 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs764912008, COSV104407269, COSV60002680; called by muse, mutect2, varscan2
- ZNF606 | c.1205A>T p.Y402F | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV58707843; called by muse, mutect2, varscan2
- ZNF619 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59031083; called by muse, mutect2, varscan2
- ZNF676 | c.1103C>A p.P368H (on ENST00000650058; = p.P336H on NM_001001411.3) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs767344565, COSV68094686; called by muse, mutect2, varscan2
- ZNF692 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 21/157 reads (13%) | catalogued as COSV60638956; called by muse, mutect2, varscan2
- ZNF708 | c.1496C>A p.T499N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63608643; called by muse, mutect2, varscan2
- ZNF761 | c.124A>T p.R42W | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV61889369; called by muse, mutect2, varscan2
- ZNF816 | c.987A>T p.R329S | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as COSV54412340; called by muse, mutect2, varscan2
- ZNF98 | c.111A>T p.L37F | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63339425; called by muse, mutect2, varscan2
- ZSCAN29 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53021043; called by muse, mutect2, varscan2
- GPR173 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- GRIN2D | c.1728_1729delinsA p.F577Sfs*11 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by pindel, varscan2*
- HJURP | c.2228dup p.L743Ffs*4 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- IGKV1-17 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LRRTM4 | c.1467del p.K489Nfs*34 (on ENST00000409093 / NM_001282924.2; = p.K489Nfs*33 on NM_024993.6) | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- MEGF10 | c.563del p.G188Vfs*148 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- MN1 | c.3576del p.Q1193Rfs*19 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- NOVA1 | c.537del p.N180Tfs*6 | Frame Shift Del (DEL) | VAF 13/127 reads (10%) | called by mutect2, pindel, varscan2
- OR2T6 | c.714dup p.A239Cfs*34 | Frame Shift Ins (INS) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- OR56B1 | c.221del p.I74Tfs*5 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- OR5H1 | c.731dup p.H244Qfs*26 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- PLA2G4A | c.264+1del | Frame Shift Del (DEL) | VAF 38/264 reads (14%) | called by mutect2, pindel, varscan2
- RBBP7 | c.928del p.H310Ifs*32 | Frame Shift Del (DEL) | VAF 16/127 reads (13%) | called by mutect2, pindel, varscan2
- RBP3 | c.2997G>T p.K999N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SEMA3E | c.1365dup p.D456Rfs*2 | Frame Shift Ins (INS) | VAF 41/158 reads (26%) | called by mutect2, pindel, varscan2
- SH3GL3 | c.327del p.F110Lfs*5 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- SPTA1 | c.5911del p.D1971Tfs*21 | Frame Shift Del (DEL) | VAF 109/296 reads (37%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.984del p.W328Cfs*6 | Frame Shift Del (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- TBPL2 | c.692del p.P231Qfs*8 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel
- TESPA1 | c.634del p.D212Tfs*108 (on ENST00000316577 / NM_001098815.3; = p.D74Tfs*108 on NM_014796.2 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/31 reads (52%) | called by mutect2, pindel*, varscan2
- TMEM62 | c.449del p.S150Ifs*37 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- TPTE | c.1171-1G>T p.X391_splice (on ENST00000618007 / NM_199261.4; = p.X373_splice on NM_199259.4) | Splice Site (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- ACSM2B | c.72C>T p.Y24= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV61659707; called by muse, mutect2, varscan2
- ADAMTS5 | c.2719C>A p.R907= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs760152877, COSV53184371; called by muse, mutect2, varscan2
- ADCY5 | c.1047C>A p.A349= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV71901586; called by muse, varscan2
- ADGRG2 | c.1014A>T p.P338= (on ENST00000379869 / NM_001079858.3; = p.P335= on NM_005756.4) | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV61340986; called by muse, mutect2, varscan2
- AIRE | c.1350C>G p.A450= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV52396675; called by muse, mutect2, varscan2
- ANXA3 | c.255G>T p.V85= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV53716667; called by muse, mutect2, varscan2
- AP3M2 | c.207G>T p.V69= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV51530351; called by muse, mutect2, varscan2
- ARHGAP20 | c.3460C>T p.L1154= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV52814693; called by muse, mutect2, varscan2
- ATP2B3 | c.1905C>A p.I635= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV54859578; called by muse, mutect2, varscan2
- ATP9A | c.129G>T p.L43= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV58771036; called by muse, mutect2, varscan2
- BICRAL | c.2751G>T p.T917= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV58407273, COSV58408122; called by muse, mutect2, varscan2
- BRD1 | c.1437C>T p.Y479= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1208303491, COSV53460983; called by mutect2, varscan2
- BRINP3 | c.1881C>A p.I627= | Silent (SNP) | VAF 109/291 reads (37%) | catalogued as COSV66537509, COSV66538659; called by muse, mutect2, varscan2
- BRS3 | c.90T>C p.D30= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV65711254; called by muse, mutect2, varscan2
- BTNL8 | c.588C>A p.T196= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV51461276, COSV99180489; called by muse, mutect2, varscan2
- CALN1 | c.468C>A p.I156= (on ENST00000329008 / NM_001017440.3; = p.I198= on NM_031468.4) | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV61126462, COSV61148451; called by muse, mutect2, varscan2
- CCDC138 | c.321A>G p.E107= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV54571256; called by muse, mutect2, varscan2
- CD22 | c.1164C>G p.P388= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV50064690; called by muse, mutect2
- CDH17 | c.2070T>C p.A690= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1293090477, COSV50338728; called by muse, mutect2, varscan2
- CHST1 | c.1065C>A p.A355= | Silent (SNP) | VAF 98/150 reads (65%) | catalogued as COSV57325358; called by muse, mutect2, varscan2
- CIAO1 | c.927G>T p.V309= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV55531768; called by muse, mutect2, varscan2
- CLIC2 | c.666T>C p.R222= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV58938304; called by muse, mutect2
- CLSTN2 | c.1521C>A p.T507= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV71724356; called by muse, mutect2, varscan2
- CNTN3 | c.2667T>C p.P889= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as COSV55182419, COSV99723412; called by muse, mutect2, varscan2
- CNTN3 | c.1278G>C p.L426= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV55182373, COSV55182426; called by muse, varscan2
- COL1A2 | c.22C>A p.R8= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV51964788; called by muse, mutect2, varscan2
- COL22A1 | c.1149G>T p.A383= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV57326795, COSV57356565; called by muse, mutect2, varscan2
- COL4A6 | c.3076C>A p.R1026= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs747433163, COSV57875864; called by muse, mutect2, varscan2
- COLEC10 | c.531G>A p.R177= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV60520829; called by muse, mutect2, varscan2
- COLEC12 | c.1128C>A p.T376= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV68373270; called by muse, mutect2, varscan2
- COP1 | c.2088A>T p.T696= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV58174648; called by muse, mutect2, varscan2
- CRHR1 | c.387C>T p.I129= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs752913275, COSV53285095; called by muse, mutect2, varscan2
- CTNND2 | c.990C>A p.R330= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV58913704, COSV58921201; called by muse, mutect2, varscan2
- DCDC1 | c.4971G>T p.P1657= (on ENST00000597505 / NM_001367979.1; = p.P764= on NM_020869.3) | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs116099904, COSV100360600; called by muse, mutect2, varscan2
- DCT | c.1353T>C p.L451= | Silent (SNP) | VAF 38/65 reads (58%) | catalogued as COSV65470553; called by muse, mutect2, varscan2
- DGKI | c.567C>A p.L189= | Silent (SNP) | VAF 55/250 reads (22%) | catalogued as COSV55971855; called by muse, mutect2, varscan2
- DLG5 | c.915G>T p.T305= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as COSV64949614; called by muse, mutect2, varscan2
- DLX1 | c.702C>A p.I234= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs758527146, COSV59395152; called by muse, mutect2, varscan2
- DMD | c.1803A>G p.Q601= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV55897192; called by muse, mutect2, varscan2
- DMD | c.1668C>T p.D556= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV55897220; called by muse, mutect2, varscan2
- DNAH10 | c.1158C>A p.T386= (on ENST00000409039; = p.T325= on NM_207437.3) | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV101292572, COSV69000113; called by muse, mutect2, varscan2
- DNAJC27 | c.165C>A p.V55= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99266602; called by muse, mutect2, varscan2
- DPP6 | c.339G>T p.S113= (on ENST00000377770 / NM_001364500.2; = p.S51= on NM_001936.5) | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs376122301; called by muse, mutect2, varscan2
- DPP6 | c.2509C>A p.R837= (on ENST00000377770 / NM_001364500.2; = p.R775= on NM_001936.5) | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV59640722; called by muse, mutect2, varscan2
- DSPP | c.378G>T p.G126= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV56815499; called by muse, mutect2, varscan2
- DST | c.4797A>G p.P1599= | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as COSV55018126; called by muse, mutect2, varscan2
- DYNC2I2 | c.633G>A p.S211= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs376954350; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHD3 | c.1047A>T p.S349= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV59032689; called by muse, mutect2, varscan2
- EIF4G2 | c.2478A>G p.L826= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs964848013, COSV60598853; called by muse, mutect2, varscan2
- ERBB4 | c.3756C>T p.T1252= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs749563712, COSV61517245; called by muse, mutect2, varscan2
- EXOC3 | c.1146G>T p.T382= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs773259161, COSV59268435; called by muse, mutect2, varscan2
- FAM24A | c.213C>A p.T71= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV100925084; called by muse, mutect2, varscan2
- FAM47A | c.54G>A p.K18= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV60495452; called by muse, mutect2, varscan2
- FAM47C | c.2274C>G p.R758= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs781979135, COSV63726405, COSV63729893; called by muse, mutect2, varscan2
- FASTKD5 | c.36A>G p.R12= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV53909000; called by muse, mutect2, varscan2
- FAT3 | c.12759G>T p.V4253= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as COSV53164402; called by muse, mutect2, varscan2
- FAT4 | c.7455C>T p.S2485= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV100628802; called by muse, mutect2
- FLT1 | c.3924C>A p.T1308= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV56740164; called by muse, mutect2
- FSIP2 | c.19065C>T p.F6355= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100555342, COSV58078695; called by muse, mutect2, varscan2
- GABRA2 | c.1347C>A p.V449= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV100734572, COSV62919132; called by muse, varscan2
- GABRP | c.723T>C p.N241= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV54665360; called by muse, mutect2, varscan2
- GAREM1 | c.1161G>T p.S387= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV52515073; called by muse, mutect2, varscan2
- GCNA | c.69T>A p.L23= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV65468077; called by muse, mutect2, varscan2
- GFI1B | c.531G>T p.G177= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV59746752; called by muse, mutect2, varscan2
- GNAS | c.909T>C p.A303= | Silent (SNP) | VAF 33/238 reads (14%) | catalogued as COSV99670191; called by muse, mutect2, varscan2
- GPR142 | c.1083C>G p.G361= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV59520320; called by muse, mutect2, varscan2
- GRXCR1 | c.355C>T p.L119= | Silent (SNP) | VAF 82/184 reads (45%) | catalogued as COSV67670520; called by muse, mutect2, varscan2
- GTF3C1 | c.837G>A p.L279= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs1178813235, COSV62244415; called by muse, mutect2, varscan2
- GUCD1 | c.444G>T p.V148= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101238122; called by muse, mutect2, varscan2
- HNRNPCL1 | c.240A>G p.V80= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV58614699; called by muse, mutect2, varscan2
- HPD | c.786T>A p.A262= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV56643469; called by muse, mutect2, varscan2
- ICE1 | c.1809T>C p.T603= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV56831153; called by muse, mutect2, varscan2
- IGF1R | c.2439G>C p.L813= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV51364287; called by muse, mutect2, varscan2
- IGSF10 | c.6103C>T p.L2035= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs1447043979, COSV56394186; called by muse, mutect2, varscan2
- IGSF3 | c.2922T>C p.C974= (on ENST00000369486 / NM_001007237.3; = p.C994= on NM_001542.4) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs776839625, COSV59597609; called by muse, mutect2, varscan2
- IKBKE | c.1215A>G p.K405= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV65626830; called by muse, mutect2, varscan2
- INMT | c.732C>A p.V244= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV50002551; called by muse, mutect2, varscan2
- IPO4 | c.1104G>A p.Q368= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs769264789, COSV55781662; called by mutect2, varscan2
- ITGA11 | c.1387C>A p.R463= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59875736; called by muse, mutect2, varscan2
- ITGA4 | c.648A>T p.P216= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV52003486; called by muse, mutect2, varscan2
- ITGB2 | c.78G>A p.T26= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs753813421, COSV56609515; called by muse, mutect2, varscan2
- KIAA1614 | c.2316C>T p.S772= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100851190, COSV62551699; called by muse, mutect2, varscan2
- KIR2DL1 | c.957T>A p.S319= | Silent (SNP) | VAF 78/385 reads (20%) | catalogued as COSV52407443; called by muse, mutect2, varscan2
- KLK4 | c.492G>T p.V164= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs868158352, COSV60677068; called by muse, mutect2, varscan2
- KMT2D | c.3030G>A p.G1010= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV56480048; called by muse, mutect2, varscan2
- KRTAP24-1 | c.78C>A p.I26= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100447443; called by muse, mutect2, varscan2
- L1CAM | c.234C>A p.P78= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV100649389, COSV62829836; called by muse, mutect2, varscan2
- LAMA4 | c.4869C>A p.L1623= (on ENST00000230538 / NM_001105206.3; = p.L1616= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV57903795; called by muse, mutect2, varscan2
- LIMK2 | c.912G>C p.L304= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100058564; called by muse, mutect2, varscan2
- LRP2 | c.9442C>A p.R3148= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs776178253, COSV55555099, COSV55570622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC7 | c.3672G>A p.A1224= (on ENST00000651989 / NM_001370785.2; = p.A1191= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs781204065, COSV50412296; called by muse, mutect2, varscan2
- LTBP1 | c.2403T>A p.T801= (on ENST00000404816 / NM_206943.4; = p.T475= on NM_000627.4) | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as COSV100616856, COSV63196526; called by muse, mutect2, varscan2
- MAGEA11 | c.1122G>T p.V374= | Silent (SNP) | VAF 145/284 reads (51%) | catalogued as COSV60758370; called by muse, mutect2, varscan2
- MAGEB6B | c.837T>C p.D279= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs757931455; called by muse, mutect2, varscan2
- MAGEC1 | c.3282C>A p.T1094= | Silent (SNP) | VAF 31/256 reads (12%) | catalogued as COSV53576412, COSV53580076; called by muse, mutect2, varscan2
- MAGEC3 | c.1806C>G p.S602= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV53578895, COSV68924219; called by muse, mutect2, varscan2
- MAP3K10 | c.687G>T p.L229= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV53424965; called by muse, mutect2, varscan2
- MAPK4 | c.1161G>C p.A387= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV68543576, COSV68543826; called by muse, mutect2
- MATN1 | c.333C>A p.I111= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV65651182; called by muse, mutect2, varscan2
- MDN1 | c.13548C>G p.L4516= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs775390100, COSV101021415, COSV65532430; called by muse, mutect2, varscan2
- MEGF10 | c.735G>T p.V245= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV57255476; called by muse, mutect2, varscan2
- METTL2B | c.6C>T p.A2= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV52310574; called by muse, mutect2, varscan2
- MIF4GD | c.306C>A p.V102= (on ENST00000325102 / NM_001370592.1; = p.V136= on NM_020679.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99821597; called by muse, mutect2, varscan2
- MMD2 | c.690G>T p.G230= (on ENST00000404774 / NM_001100600.2; = p.G206= on NM_198403.4) | Silent (SNP) | VAF 45/91 reads (49%) | catalogued as COSV101287022; called by muse, mutect2, varscan2
- MME | c.87C>A p.I29= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as COSV100852413; called by muse, mutect2, varscan2
- MSLNL | c.1122G>T p.R374= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV53505705; called by muse, mutect2, varscan2
- MTMR7 | c.1875C>G p.S625= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs146319076, COSV51669873, COSV51669916; called by muse, mutect2, varscan2
- MUC5B | c.75C>T p.T25= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1236059312, COSV71590624, COSV71594878; called by muse, mutect2
- MXRA5 | c.3678C>A p.S1226= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV54247877; called by muse, mutect2, varscan2
- MYCN | c.954G>T p.L318= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99808315; called by muse, mutect2, varscan2
- MYH7 | c.2877G>C p.L959= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV62523091; called by muse, mutect2, varscan2
- MYO7B | c.3144G>T p.L1048= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV67351301; called by muse, mutect2, varscan2
- MYRIP | c.6G>C p.G2= | Silent (SNP) | VAF 66/121 reads (55%) | catalogued as COSV56879606; called by muse, mutect2, varscan2
- NCAN | c.2613G>T p.T871= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs375566714, COSV53057328; called by muse, mutect2, varscan2
- NOC2L | c.2046G>T p.S682= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as rs149040522, COSV58990537; called by muse, mutect2, varscan2
- NPHP3 | c.3054T>A p.A1018= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as COSV58632989; called by muse, mutect2
- NYAP2 | c.798C>T p.A266= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as rs779640204, COSV56001563; called by muse, mutect2, varscan2
- OCA2 | c.2460C>A p.S820= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV62356394; called by muse, mutect2, varscan2
- OPLAH | c.864G>C p.S288= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1554759938, COSV70679130; called by muse, mutect2, varscan2
- OR13F1 | c.726A>G p.T242= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100594777; called by muse, mutect2, varscan2
- OR14A16 | c.894G>A p.L298= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV62927386; called by muse, mutect2, varscan2
- OR14I1 | c.429A>T p.A143= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1396312758, COSV61200734; called by muse, mutect2
- OTOP2 | c.414G>T p.L138= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs770391462, COSV58883484; called by muse, mutect2, varscan2
- PCDHA3 | c.1176C>T p.H392= | Silent (SNP) | VAF 59/129 reads (46%) | catalogued as COSV63545415; called by muse, mutect2, varscan2
- PCDHGA5 | c.2334G>T p.T778= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs1477897734, COSV54016470, COSV54017936; called by muse, mutect2, varscan2
- PCNX2 | c.825G>T p.P275= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV50867675; called by muse, mutect2, varscan2
- PDCD11 | c.3873C>T p.N1291= | Silent (SNP) | VAF 68/238 reads (29%) | catalogued as rs753298022, COSV63933790; called by muse, mutect2, varscan2
- PDE4D | c.1698C>A p.V566= (on ENST00000340635 / NM_001104631.2; = p.V430= on NM_006203.4) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV57720258; called by muse, mutect2, varscan2
- PIK3R4 | c.2310T>G p.L770= | Silent (SNP) | VAF 87/162 reads (54%) | catalogued as COSV63243640, COSV63244056; called by muse, mutect2, varscan2
- PKD1L1 | c.7269G>A p.E2423= | Silent (SNP) | VAF 60/133 reads (45%) | catalogued as COSV51844642; called by muse, mutect2, varscan2
- PKHD1L1 | c.861G>T p.T287= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65751234; called by muse, mutect2
- PKHD1L1 | c.2694G>T p.G898= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as COSV101006218; called by muse, mutect2, varscan2
- PM20D1 | c.1059C>T p.P353= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV65649552; called by muse, mutect2, varscan2
- RANBP2 | c.3147A>G p.P1049= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs749127004, COSV51707385; called by muse, mutect2, varscan2
- RHCG | c.885C>A p.T295= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV51516404, COSV51518196; called by muse, mutect2, varscan2
- RNF10 | c.1356G>A p.E452= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV58047770; called by muse, mutect2, varscan2
- RP1L1 | c.3012G>T p.G1004= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV101223291, COSV66758746; called by muse, mutect2
- RPS6KA1 | c.1236G>T p.L412= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV65177677; called by muse, mutect2, varscan2
- S100A5 | c.87G>C p.L29= | Silent (SNP) | VAF 18/147 reads (12%) | catalogued as COSV100573112; called by muse, mutect2, varscan2
- SEL1L2 | c.993C>A p.A331= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV53156923; called by muse, mutect2, varscan2
- SLC12A5 | c.2304G>T p.V768= (on ENST00000454036 / NM_001134771.2; = p.V745= on NM_020708.5) | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV54800744; called by muse, mutect2, varscan2
- SLC25A24 | c.1218G>A p.L406= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99916291; called by muse, mutect2, varscan2
- SLC34A3 | c.141C>A p.L47= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as COSV63187949; called by muse, mutect2, varscan2
- SLC9A4 | c.84T>A p.S28= | Silent (SNP) | VAF 54/227 reads (24%) | catalogued as COSV54838390; called by muse, mutect2, varscan2
- SMAD3 | c.231G>T p.V77= | Silent (SNP) | VAF 19/262 reads (7%) | catalogued as COSV100529067; called by muse, mutect2
- SMARCA1 | c.267C>A p.A89= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV64413517; called by muse, mutect2, varscan2
- SMU1 | c.306C>T p.P102= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as rs1163852787, COSV68140260; called by muse, mutect2, varscan2
48 further variants in this file (0 protein-altering or splice-affecting, 22 silent, 26 other) are not listed here.
